Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A8VF, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A8VF-01A (Primary Tumor).

[page 1 of 2]
Surgery date:

ICD-0-3
Leiomyosarcoma NOS 8890/3
Site Leg NOS C49.2
JN 1/21/14

SPECIMENS:

- A. RIGHT LEG
- B. SCIATIC NERVE MARGIN
- C. FEMORAL NERVE

DIAGNOSIS:

- A. RIGHT LEG, ABOVE KNEE AMPUTATION:
- HIGH GRADE SARCOMA WITH NECROSIS MOST CONSISTENT WITH PLEOMORPHIC LEIOMYOSARCOMA.
- TUMOR IS 12.0 CM IN MAXIMUM DIMENSION.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR (SEE ALSO SPECIMEN B).
- TUMOR IS ADJACENT TO, BUT DOES NOT INVADE, FIBULA.
- SEE NOTE.
- FOUR POPLITEAL LYMPH NODES NEGATIVE FOR MALIGNANCY (0/4).
- B. SCIATIC NERVE, MARGIN, BIOPSY:
- NERVE AND ADJACENT FIBROADIPOSE, NEGATIVE FOR MALIGNANCY.
- C. FEMORAL NERVE, BIOPSY:
- NERVE AND ADJACENT FIBROADIPOSE, NEGATIVE FOR MALIGNANCY.

NOTE: The tumor present in the lower leg is extremely pleomorphic and has a moderate amount of necrosis. Although in many areas these cells are somewhat polygonal and occasionally multinucleate, there are other areas where the tumor has a more spindled morphology. The tumor is strongly positive for desmin, and shows patchy strong staining for HHF35 (MSA). There is also very focal staining for smooth muscle actin (SMA). It is negative for myoglobin, myo D1 and myogenin (markers that would suggest rhabdomyosarcomatous differentiation). Overall the immunophenotype and morphology are consistent with pleomorphic variant of leiomyosarcoma. Dr. has seen this case and agrees.

SPECIMEN(S):

A. RIGHT LEG B. SCIATIC NERVE MARGIN C. FEMORAL NERVE

CLINICAL HISTORY:

None given

GROSS DESCRIPTION:

A. RIGHT LEG:
Received fresh is a right leg measuring 75 cm. in length. The right foot measures 27x9x4 cm. and is grossly unremarkable. The upper leg measures 25 cm. in length. The lower leg measures 60 cm. in length. Tumor measuring 12x9x9 cm. is present at the posterior lateral aspect of the calf. The tumor is 1.0 cm. away from the posterior skin surface, 6.0 cm. to the medial skin surface, 3.0 cm. to the anterior skin surface. The tumor is present at the lateral skin surface and the overlying ulcer measures 4.0x4.0 cm. The tumor is serially sectioned. The cut surface is solid with red tumor reaching but not grossly invading the adjacent fibular bone. The tumor is well separated from the tibia. The tumor is also greater than 40 cm from the proximal surgical margins. Multiple lymph nodes are found in the popliteal area adjacent to vascular structures. Representative sections are submitted as follows:
Cassette A1: skin at surgical margin
Cassette A2: soft tissue and skeletal muscle from the surgical margin
Cassette A3: artery and vein
Cassette A4: popliteal vein at margin
Cassette A5: blood vessel from the lateral aspect of the surgical margin
Cassette A6-A12: multiple popliteal lymph nodes (as follows)
Cassette A6-A7: one lymph node trisected
Cassette A8: one lymph node bisected
Cassette A9-A12: multiple possible lymph nodes
Cassette A13-A20: tumor
Cassette A13-A14: tumor and skin from the lateral aspect

[page 2 of 2]
Surgery date:

Cassette A15: tumor and skin from posterior aspect
Cassette A16-A25: representative sections from the tumor
Cassette A26: representative section from the fibular bone which is next to tumor
Cassette A27-A28: surgical margin at femoral bone

B. SCIATIC NERVE MARGIN:

Received in formalin is a piece of soft tissue measuring 2.5x1.5x1.0 cm. The surface of the specimen is inked black. The specimen is then serially sectioned and submitted in toto in cassette B1-B3.

C. FEMORAL NERVE:

Received in formalin is a piece of pink-tan tissue measuring 5.0x1.9 cm. Representative sections are taken and submitted in cassette C1 through C3.

Source: NCI Genomic Data Commons file 1fd1bb0d-d98e-45c6-b0fd-60eb7b00e74a (TCGA-QQ-A8VF.F1E41A62-384F-44D1-8898-AB22F4CF4E8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).